CCDI case PBCSVE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/2fa49d41-7167-4db9-9004-c34556fce6b6

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 4.0 years (1,469 days).

Biospecimens (2 samples)
- Sample 0DZQ8O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZQ8T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
